Somatic mutation profile of tumor specimen MP2PRT-PAUJUL-TMP1-A (aliquot MP2PRT-PAUJUL-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUJUL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,095 days).
Specimen MP2PRT-PAUJUL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8e67c9-9df2-4552-9d2f-3c4f62f80bb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJUL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJUL-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60c82a6c-71de-4efd-b850-18f0e2f272ce

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP47 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs938652041; called by muse, mutect2, varscan2
- CSPG4 | c.5984G>A p.R1995Q | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400079579; called by muse, mutect2, varscan2
- DDC | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV63565075; called by muse, mutect2
- ESYT1 | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs371562380; called by muse, mutect2, varscan2
- FGFR2 | c.1086G>A p.A362= | Splice Region (SNP) | VAF 76/177 reads (43%) | catalogued as rs151250769, COSV60642690; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCKAP5 | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs779991490, COSV58427765; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- TLE7 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.871); catalogued as rs970495782, COSV73722753; called by muse, mutect2, varscan2
- ASXL2 | c.1331_1332insGGCG p.E445Afs*5 | Frame Shift Ins (INS) | VAF 81/225 reads (36%) | called by mutect2, pindel*, varscan2
- MSH6 | c.2803_2820delinsCGGGCA p.S935_Q939delinsR | In Frame Del (DEL) | VAF 15/114 reads (13%) | called by muse*, pindel
- CACNA1H | c.4656C>T p.G1552= | Silent (SNP) | VAF 159/469 reads (34%) | catalogued as rs1427676254, COSV61984437; called by muse, mutect2, varscan2
- DSG3 | c.1833G>A p.P611= | Silent (SNP) | VAF 143/522 reads (27%) | catalogued as rs774111652, COSV57127010; called by muse, mutect2, varscan2
- EGFR | c.3351C>T p.P1117= | Silent (SNP) | VAF 140/299 reads (47%) | catalogued as rs149995949; called by muse, mutect2, varscan2
- SPTBN4 | c.6619C>T p.L2207= | Silent (SNP) | VAF 203/496 reads (41%) | called by muse, mutect2, varscan2
